CPTAC case C3L-02967 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3b417f44-bc66-4989-8a74-bee69e7f4050

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 74.4 years (27,172 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA2; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,974 days (5.4 years); Progression or recurrence: yes; Days to last follow up: 1,974 days (5.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 396 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 701 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 704 days (1.9 years); Disease response: Complete Response.
- Days to follow up: 1,069 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,426 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,974 days (5.4 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 104.78 kg; Height: 175.26 cm; BMI: 34.11; DLCO (% of predicted): 98; FEV1/FVC after bronchodilator (%): 83; FEV1/FVC before bronchodilator (%): 84.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 43; Cigarettes per day: 20; Tobacco smoking onset year: 1961; Tobacco smoking quit year: 2004; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 43.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02967-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 202 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02967-21: Section location: Left Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-02967-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 226 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02967-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
